Somatic mutation profile of tumor specimen C3N-01944-01 (aliquot CPT0163480006) from CPTAC case C3N-01944, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 65.9 years (24,082 days).
Specimen C3N-01944-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a0ba64b-5c15-4df3-b1fd-8875f2ab69d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01944-31 (Blood Derived Normal), aliquot CPT0163520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667328f6-373a-4bb9-b4c6-7237cfadae60

The open-access MAF lists 149 somatic variants for this specimen: 93 protein-altering or splice-affecting, 31 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 31, RNA 8, Intron 7, 5'UTR 4, Nonsense Mutation 4, 5'Flank 3, Splice Site 2, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 95/678 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 53/349 reads (15%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, varscan2
- AKR1C3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV65911218; called by muse, mutect2, varscan2
- APC2 | c.4874C>T p.A1625V | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs1321678250; called by muse, mutect2
- ATIC | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327150251; called by muse, mutect2, varscan2
- C16orf71 | c.450C>A p.D150E | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs772676145, COSV73918502; called by muse, mutect2, varscan2
- DAPK3 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1289429252; called by muse, mutect2, varscan2
- DMAP1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60000932; called by muse, mutect2, varscan2
- DOLK | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 68/842 reads (8%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); catalogued as COSV65364265; called by muse, mutect2
- DPPA4 | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV100169142; called by muse, mutect2, varscan2
- FAM131B | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68125847; called by muse, mutect2
- FCAMR | c.1280_1309del p.I427_W436del | In Frame Del (DEL) | VAF 36/225 reads (16%) | catalogued as rs1402390421; called by mutect2, varscan2*
- GAB3 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1436457813; called by muse, mutect2, varscan2
- GLOD5 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs781844927, COSV57488815; called by muse, mutect2, varscan2
- GRIA2 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52382152; called by muse, mutect2, varscan2
- GSN | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 42/644 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs151155909; called by muse, mutect2
- IRS2 | c.2240G>A p.C747Y | Missense Mutation (SNP) | VAF 105/492 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV65479837; called by muse, mutect2, varscan2
- KCNJ3 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.59); catalogued as COSV99715793; called by muse, mutect2
- KRTAP4-5 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 76/545 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs753071714; called by muse, mutect2, varscan2
- MGAT4C | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV59830563; called by muse, mutect2
- MTR | c.3523C>T p.P1175S | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1182672054; called by muse, mutect2
- MYO1E | c.1806G>A p.R602= | Splice Region (SNP) | VAF 14/242 reads (6%) | catalogued as rs762347672; called by muse, mutect2
- NOD2 | c.2506A>G p.I836V | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs752881716; called by muse, mutect2
- NR6A1 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.481); catalogued as rs1412762293, COSV60633208; called by muse, mutect2
- NT5C1B | c.835G>A p.E279K (on ENST00000359846 / NM_001199086.2; = p.E219K on NM_033253.4) | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs909645864; called by muse, varscan2
- PITPNM1 | c.3145G>A p.V1049M | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451190681, COSV99653710; called by muse, mutect2, varscan2
- PPP2R2C | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs764052676; called by muse, mutect2, varscan2
- PPP4R3B | c.2116G>A p.A706T (on ENST00000616407 / NM_001122964.3; = p.A621T on NM_020463.4) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs374171261; called by muse, mutect2, varscan2
- PSMB10 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 59/449 reads (13%) | catalogued as COSV99863088; called by muse, mutect2, varscan2
- SMARCC1 | c.3190C>T p.R1064W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs917008465; called by muse, varscan2
- SPR | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318055; called by mutect2, varscan2
- SYNM | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.45); catalogued as rs782615428; called by muse, mutect2
- TLR1 | c.1517C>A p.S506* | Nonsense Mutation (SNP) | VAF 39/303 reads (13%) | catalogued as COSV58303872; called by muse, mutect2, varscan2
- TTN | c.16646G>T p.G5549V (on ENST00000591111; = p.G4622V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/222 reads (6%) | PolyPhen possibly damaging (0.859); catalogued as COSV59968979; called by muse, mutect2
- UNC13A | c.1970C>G p.T657R | Missense Mutation (SNP) | VAF 75/486 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV53200961; called by muse, mutect2, varscan2
- USP31 | c.2147A>G p.H716R | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs775972538; called by muse, mutect2
- VIP | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65888783, COSV65889004; called by muse, mutect2, varscan2
- VPS51 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs765322623; called by muse, mutect2, varscan2
- ZNF385B | c.241A>C p.S81R | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as rs1404950801; called by muse, mutect2, varscan2
- ABCC6 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 95/668 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ABCC9 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 41/506 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2
- ALG10 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2
- ARHGAP21 | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- ASCC3 | c.2779A>G p.R927G | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ATG2B | c.4540G>A p.V1514I | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ATP1A1 | c.2012A>T p.K671M | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BMP5 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.124); called by muse, mutect2
- C5 | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CARD16 | c.12_15del p.K4Nfs*2 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by mutect2, varscan2
- CCDC81 | c.1691A>T p.E564V (on ENST00000445632 / NM_001156474.2; = p.E474V on NM_021827.4) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by mutect2, varscan2
- CDH26 | c.2095A>C p.K699Q (on ENST00000348616 / NM_177980.4; = p.K32Q on NM_021810.6) | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- CDH8 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CEP290 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CFAP46 | c.7269G>T p.E2423D | Missense Mutation (SNP) | VAF 84/510 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CLIP4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CPNE3 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CTTNBP2 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 39/491 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- CWF19L2 | c.2049A>T p.Q683H | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DYSF | c.5399C>T p.P1800L | Missense Mutation (SNP) | VAF 58/499 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA10 | c.520A>T p.N174Y | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETS2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 41/575 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- EYA4 | c.1741A>G p.S581G (on ENST00000531901 / NM_001301013.1; = p.S575G on NM_004100.5) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GRIK2 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- KCTD9 | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- KHDRBS1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2
- KRT20 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 20/394 reads (5%) | called by muse, mutect2
- LAMA5 | c.6148C>A p.R2050S | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LILRA6 | c.1077A>T p.E359D | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, varscan2
- MDN1 | c.13166A>C p.E4389A | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLE1 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 81/556 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN1 | c.1996T>A p.S666T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- OR5H2 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OTUD7B | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.146); called by muse, mutect2
- PACS1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHB15 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PLK1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PRKAA1 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRUNE1 | c.40-1G>A p.X14_splice | Splice Site (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RPUSD2 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S1PR5 | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLC13A5 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX32 | c.253-1G>C p.X85_splice | Splice Site (SNP) | VAF 62/678 reads (9%) | called by muse, mutect2
- SNX9 | c.1541del p.I514Kfs*4 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel
- TMEM200C | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TNXB | c.6686C>G p.P2229R (on ENST00000647633; = p.P1982R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TRAPPC9 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.265); called by muse, mutect2
- TRAT1 | c.549A>T p.E183D | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.188); called by muse, varscan2
- TRIM39 | c.467A>T p.K156M | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TTN | c.97460T>G p.V32487G (on ENST00000591111; = p.V25063G on NM_003319.4) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | PolyPhen possibly damaging (0.873); called by muse, mutect2
- USP40 | c.2884G>T p.G962C | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- WDR86 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA7 | c.576G>A p.Q192= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1441536335; called by muse, mutect2, varscan2
- ADAMTS10 | c.1182C>T p.I394= | Silent (SNP) | VAF 50/576 reads (9%) | catalogued as rs987567465, COSV54353854; ClinVar: likely benign; called by muse, mutect2
- ADAMTS7 | c.2445C>T p.H815= | Silent (SNP) | VAF 16/265 reads (6%) | catalogued as rs368551292; called by muse, mutect2
- AKAP12 | c.3831C>T p.D1277= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as rs756720446, COSV53574438; called by muse, mutect2, varscan2
- ASIC5 | c.267A>G p.T89= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as rs1320391350; called by muse, mutect2
- ATP1A2 | c.2745C>T p.C915= | Silent (SNP) | VAF 89/524 reads (17%) | called by muse, mutect2, varscan2
- CHD5 | c.1152C>T p.C384= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1164480071; called by muse, mutect2, varscan2
- CNTNAP2 | c.18C>T p.R6= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as COSV62265327; called by muse, mutect2, varscan2
- F8 | c.2217G>A p.E739= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs781850654; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM193B | c.984G>A p.G328= | Silent (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- FERMT3 | c.1752C>T p.A584= (on ENST00000279227 / NM_178443.3; = p.A580= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 77/527 reads (15%) | catalogued as rs201768021, COSV54172098; called by muse, mutect2, varscan2
- FOXG1 | c.1272G>A p.P424= | Silent (SNP) | VAF 82/649 reads (13%) | catalogued as rs757300535, COSV57397063; called by muse, mutect2, varscan2
- GEMIN6 | c.366C>T p.D122= | Silent (SNP) | VAF 51/317 reads (16%) | catalogued as rs200834111; called by muse, mutect2, varscan2
- GRIN2A | c.57C>T p.R19= | Silent (SNP) | VAF 76/409 reads (19%) | catalogued as rs1443213122, COSV58059234; called by muse, mutect2, varscan2
- HOXC12 | c.336C>T p.R112= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2
- KPNA6 | c.1059G>A p.R353= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- MACIR | c.150C>T p.G50= | Silent (SNP) | VAF 73/456 reads (16%) | called by muse, mutect2, varscan2
- MUC19 | c.126C>T p.T42= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1316852567, COSV101373728; called by muse, mutect2
- NAGK | c.858G>A p.A286= | Silent (SNP) | VAF 50/367 reads (14%) | catalogued as rs377566712; called by muse, mutect2, varscan2
- NPTX2 | c.984C>T p.D328= | Silent (SNP) | VAF 48/303 reads (16%) | catalogued as rs781445701, COSV55719214; called by muse, mutect2, varscan2
- OR5H1 | c.387T>C p.P129= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs771230897; called by muse, mutect2
- P2RY8 | c.669G>A p.T223= | Silent (SNP) | VAF 50/710 reads (7%) | catalogued as rs370852351, COSV101183981; called by muse, mutect2
- PCDHA1 | c.1110C>T p.A370= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as COSV65376299; called by muse, mutect2, varscan2
- POLR1G | c.936G>A p.Q312= | Silent (SNP) | VAF 60/359 reads (17%) | called by muse, mutect2, varscan2
- RAD9A | c.15C>T p.V5= | Silent (SNP) | VAF 55/386 reads (14%) | catalogued as rs572052350; called by muse, mutect2, varscan2
- RFX1 | c.1947G>A p.A649= | Silent (SNP) | VAF 43/231 reads (19%) | catalogued as rs373319604; called by muse, mutect2, varscan2
- SMTNL2 | c.1347C>T p.Y449= (on ENST00000389313 / NM_001114974.2; = p.Y305= on NM_198501.3) | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as rs140620311; called by muse, mutect2, varscan2
- SOX13 | c.1248C>T p.P416= | Silent (SNP) | VAF 51/218 reads (23%) | catalogued as rs748328420; called by muse, mutect2, varscan2
- STK31 | c.411T>C p.S137= | Silent (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- TRIM58 | c.1311C>T p.N437= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- ZSWIM7 | c.30G>A p.E10= | Silent (SNP) | VAF 137/903 reads (15%) | catalogued as rs1457507783; called by muse, mutect2, varscan2
- AC018563.1 | n.687G>A | RNA (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- ADAMTS7 | c.2376+123G>A | Intron (SNP) | VAF 55/367 reads (15%) | called by muse, mutect2, varscan2
- ADD2 | c.-167A>T | 5'UTR (SNP) | VAF 44/332 reads (13%) | called by muse, mutect2, varscan2
- AL353753.1 | n.434A>G | RNA (SNP) | VAF 55/198 reads (28%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504714 A>T | 5'Flank (SNP) | VAF 30/167 reads (18%) | catalogued as rs766844338; called by muse, mutect2, varscan2
- APTX | c.-111+190G>A | Intron (SNP) | VAF 66/296 reads (22%) | called by muse, varscan2
- B9D1 | c.404+156T>A | Intron (SNP) | VAF 36/456 reads (8%) | called by muse, mutect2
- CCDC39 | chr3:180679729 ins T | 5'Flank (INS) | VAF 38/293 reads (13%) | called by mutect2, pindel, varscan2
- CD300LG | c.885+691G>T | Intron (SNP) | VAF 75/428 reads (18%) | called by muse, mutect2, varscan2
- EIF4G3 | c.-173C>T | 5'UTR (SNP) | VAF 39/384 reads (10%) | catalogued as rs932584590; called by muse, mutect2, varscan2
- FAM3B | n.78G>A | RNA (SNP) | VAF 25/350 reads (7%) | catalogued as rs975982135; called by muse, mutect2
- FRRS1 | c.1596+23G>A | Intron (SNP) | VAF 19/93 reads (20%) | catalogued as rs778573568; called by muse, mutect2, varscan2
- HAS3 | chr16:69118442 C>A | 3'Flank (SNP) | VAF 36/549 reads (7%) | called by muse, mutect2
- KDELR2 | c.*60A>G | 3'UTR (SNP) | VAF 60/411 reads (15%) | called by muse, mutect2, varscan2
- MIR146A | n.78G>T | RNA (SNP) | VAF 16/97 reads (16%) | catalogued as rs529455292; called by muse, mutect2
- OR1F2P | n.852G>T | RNA (SNP) | VAF 26/179 reads (15%) | catalogued as rs746655090; called by muse, mutect2, varscan2
- PIPSL | n.454C>T | RNA (SNP) | VAF 20/424 reads (5%) | catalogued as rs756748645; called by muse, mutect2
- PPP1R15A | c.-207T>A | 5'UTR (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158983 G>A | 5'Flank (SNP) | VAF 32/277 reads (12%) | catalogued as rs1367711721; called by muse, mutect2, varscan2
- SLC51A | c.886+22T>A | Intron (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- TPTE2P1 | n.609A>G | RNA (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- TUBB7P | n.229C>T | RNA (SNP) | VAF 71/642 reads (11%) | catalogued as rs1158074924; called by muse, mutect2, varscan2
- UBE3A | c.-73C>A | 5'UTR (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- WBP1 | c.69+322A>G | Intron (SNP) | VAF 64/403 reads (16%) | called by muse, mutect2, varscan2
- ZNF586 | c.*35C>G | 3'UTR (SNP) | VAF 16/278 reads (6%) | catalogued as COSV74081796; called by muse, mutect2
